Somatic mutation profile of tumor specimen TCGA-56-6545-01A (aliquot TCGA-56-6545-01A-11D-1817-08) from TCGA case TCGA-56-6545, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.8 years (28,400 days).
Specimen TCGA-56-6545-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cbf6c8f-9feb-4cad-8c8a-fdd5b91de49a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-6545-10A (Blood Derived Normal), aliquot TCGA-56-6545-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bffeb800-23b6-4b29-9426-2b3da2518467

The open-access MAF lists 299 somatic variants for this specimen: 238 protein-altering or splice-affecting, 60 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 206, Silent 60, Nonsense Mutation 18, Splice Site 6, Frame Shift Del 4, Splice Region 3, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 25/66 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB10 | c.1278G>T p.M426I | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.086); catalogued as COSV60621110, COSV60622695; called by muse, mutect2, varscan2
- ACR | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53361017; called by muse, mutect2, varscan2
- ADAMTS13 | c.2048G>C p.R683P | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV63021221, COSV63021893; called by muse, mutect2, varscan2
- ADAMTS20 | c.2816G>T p.G939V | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV67129016; called by muse, mutect2, varscan2
- ADAMTS20 | c.2815G>T p.G939* | Nonsense Mutation (SNP) | VAF 26/172 reads (15%) | catalogued as COSV67131257; called by muse, varscan2
- ADAMTS7 | c.1939G>C p.A647P | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV66307182; called by muse, mutect2, varscan2
- ADGRE1 | c.1737C>A p.C579* | Nonsense Mutation (SNP) | VAF 28/156 reads (18%) | catalogued as COSV51675347; called by muse, mutect2, varscan2
- AGAP2 | c.1975G>A p.E659K (on ENST00000547588 / NM_001122772.2; = p.E323K on NM_014770.4) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as rs772641164, COSV57728061; called by muse, mutect2, varscan2
- AL121899.2 | c.1287G>A p.W429* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as rs770298668, COSV67350602; called by muse, mutect2, varscan2
- AL592490.1 | c.2112G>T p.Q704H | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101308124, COSV69426207; called by muse, mutect2
- ALKBH8 | c.369G>C p.V123= | Splice Region (SNP) | VAF 12/60 reads (20%) | catalogued as COSV52835246; called by muse, mutect2, varscan2
- ANK2 | c.8563G>C p.V2855L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV52160542; called by muse, mutect2, varscan2
- ASB9 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.058); catalogued as COSV66851701; called by muse, mutect2, varscan2
- ASB9 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as COSV66851708; called by muse, mutect2, varscan2
- ATG14 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 21/31 reads (68%) | catalogued as COSV55956504; called by muse, mutect2, varscan2
- ATP1A3 | c.1559G>C p.R520P (on ENST00000545399 / NM_001256214.2; = p.R507P on NM_152296.5) | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV57487498; called by muse, mutect2, varscan2
- BRINP2 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV64177436; called by muse, mutect2, varscan2
- C16orf92 | c.194G>T p.R65I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs375771294, COSV54226833; called by muse, mutect2, varscan2
- CACNA1F | c.4117G>T p.V1373L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as COSV59904403; called by muse, mutect2, varscan2
- CALB2 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs954413837, COSV56939358; called by muse, mutect2, varscan2
- CARS1 | c.1952G>C p.R651T | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV53454154; called by muse, mutect2, varscan2
- CCDC148 | c.1540G>T p.A514S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV51754023, COSV51760035; called by muse, mutect2, varscan2
- CDH11 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51761355; called by muse, mutect2, varscan2
- CEP290 | c.5436A>C p.E1812D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58351685; called by muse, varscan2
- CEP350 | c.4646A>G p.Q1549R | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as COSV62602254; called by muse, mutect2, varscan2
- CFHR2 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as COSV66381071; called by muse, mutect2, varscan2
- CLIP1 | c.3294G>A p.M1098I (on ENST00000620786 / NM_001247997.1; = p.M1087I on NM_002956.2) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV56801636; called by muse, mutect2, varscan2
- CNGB3 | c.129G>T p.Q43H | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV60689605; called by muse, mutect2, varscan2
- CNTNAP2 | c.2010C>A p.D670E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1343399837, COSV62178865; called by muse, mutect2, varscan2
- CNTNAP4 | c.3170T>C p.F1057S | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV56679409; called by muse, mutect2, varscan2
- COL6A5 | c.6289G>T p.V2097L (on ENST00000312481; = p.V2093L on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55201282; called by muse, mutect2, varscan2
- CRHR2 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV59265287; called by muse, mutect2, varscan2
- CSMD3 | c.9829G>A p.G3277S (on ENST00000297405 / NM_001363185.1; = p.G3108S on NM_052900.3) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52176991, COSV99841236; called by muse, mutect2, varscan2
- CTNNA2 | c.1278C>G p.N426K | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.452); catalogued as COSV58146218; called by muse, mutect2, varscan2
- CUBN | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64715419; called by muse, mutect2
- CUL4B | c.2727C>A p.Y909* | Nonsense Mutation (SNP) | VAF 17/121 reads (14%) | catalogued as COSV60687310; called by muse, varscan2
- DACH2 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as COSV64168597; called by muse, mutect2, varscan2
- DCLRE1A | c.2743G>C p.E915Q | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV63748708; called by muse, mutect2, varscan2
- DDX60L | c.1920C>G p.C640W | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52713389; called by muse, mutect2, varscan2
- DEFA4 | c.161T>C p.L54P | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as rs753521273, COSV52404706; called by muse, mutect2, varscan2
- DNAH7 | c.8238G>A p.M2746I | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV56764338; called by muse, mutect2, varscan2
- DNAH9 | c.1538C>A p.S513Y | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.013); catalogued as COSV52348910; called by muse, mutect2, varscan2
- DNAJC27 | c.300G>C p.Q100H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1246652886, COSV53095091; called by muse, mutect2, varscan2
- DOT1L | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 18/495 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.157); catalogued as COSV67109689, COSV67109921; called by muse, mutect2
- DSEL | c.2205G>T p.K735N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV59491405; called by muse, mutect2, varscan2
- ECI1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs72766670, COSV57043580; called by muse, mutect2, varscan2
- EIF3A | c.3050C>A p.P1017Q | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.368); catalogued as COSV64961386; called by muse, mutect2, varscan2
- EIF3L | c.1230A>C p.E410D | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV67739616; called by muse, mutect2, varscan2
- ENPP4 | c.335G>C p.W112S | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775322000, COSV100320344, COSV58088960; called by muse, mutect2, varscan2
- ETV1 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54142272, COSV54154591; called by muse, mutect2, varscan2
- ETV3 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58748039; called by muse, mutect2, varscan2
- FAM13A | c.659T>C p.M220T | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs748485574, COSV52002393; called by muse, mutect2, varscan2
- FAT3 | c.545C>A p.A182E | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53108616; called by muse, mutect2, varscan2
- FLNC | c.2693del p.G898Afs*24 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as COSV57950740; called by mutect2, pindel, varscan2
- FMN2 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV60429885; called by muse, mutect2, varscan2
- FMN2 | c.1930+1G>T p.X644_splice | Splice Site (SNP) | VAF 12/65 reads (18%) | catalogued as COSV60429891; called by muse, mutect2, varscan2
- FMO1 | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV61445719; called by muse, mutect2, varscan2
- FRMD4B | c.2699G>T p.R900L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs533947293, COSV68329960; called by muse, mutect2, varscan2
- GC | c.160A>C p.S54R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV56737219; called by muse, mutect2
- GFOD2 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV52057882; called by muse, mutect2, varscan2
- GRM7 | c.890C>G p.A297G | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs1297876594, COSV63142857; called by muse, mutect2, varscan2
- H2BC7 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61911670, COSV61911915; called by muse, mutect2, varscan2
- H4C2 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.622); catalogued as COSV55138112, COSV55138824; called by muse, mutect2, varscan2
- HAND1 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.798); catalogued as COSV50562605; called by muse, mutect2, varscan2
- HAUS1 | c.618A>T p.R206S | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV56363348; called by muse, mutect2, varscan2
- HCN2 | c.938A>T p.D313V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV52114548; called by muse, mutect2, varscan2
- HECW1 | c.4592T>A p.L1531Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67829166; called by muse, mutect2, varscan2
- HERC2 | c.10023G>C p.Q3341H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as COSV55323128; called by muse, varscan2
- HJV | c.364C>A p.Q122K (on ENST00000336751 / NM_213653.4; = p.Q9K on NM_145277.5) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV60951992; called by muse, varscan2
- HMCN1 | c.10513A>G p.T3505A | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV54899595, COSV54930812; called by muse, mutect2, varscan2
- HSPG2 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV65930322; called by muse, mutect2, varscan2
- IGHV3-30 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 34/694 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.361); catalogued as rs775745945; called by muse, mutect2
- IL7R | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV57408492; called by muse, mutect2, varscan2
- INPP5D | c.2125G>C p.E709Q (on ENST00000445964 / NM_001017915.3; = p.E708Q on NM_005541.5) | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.218); catalogued as COSV64036941; called by muse, mutect2, varscan2
- IRF8 | c.590C>A p.A197E | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV51898013; called by muse, mutect2, varscan2
- ITM2A | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV64810972; called by muse, mutect2, varscan2
- ITPRID1 | c.2494T>C p.C832R | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1459975521, COSV60074470; called by muse, mutect2, varscan2
- KAT6A | c.4532A>T p.Q1511L | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55905909; called by muse, mutect2, varscan2
- KCNH8 | c.2672T>A p.V891E | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV60463489; called by muse, varscan2
- KCNH8 | c.2698T>A p.S900T | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV60463494; called by muse, varscan2
- KCTD21 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as rs1341036827, COSV60741092; called by muse, mutect2, varscan2
- KLHL14 | c.839C>A p.S280* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | catalogued as COSV63832356; called by muse, mutect2, varscan2
- KMT2D | c.2002G>T p.E668* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV56438771, COSV56438888; called by muse, mutect2, varscan2
- KNG1 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV53977693; called by muse, mutect2, varscan2
- LGI4 | c.1187G>T p.R396L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.478); catalogued as COSV59533523; called by muse, mutect2
- LMOD1 | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV66172664; called by muse, mutect2, varscan2
- LRP1B | c.8131C>A p.R2711S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV67218188; called by muse, mutect2, varscan2
- MACC1 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV60542798, COSV60546504; called by muse, mutect2, varscan2
- MAGEA12 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV63294790; called by muse, mutect2, varscan2
- MAGEB2 | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.773); catalogued as COSV66780712, COSV66780884; called by muse, mutect2, varscan2
- MAP3K19 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.827); catalogued as COSV59638803; called by muse, mutect2, varscan2
- MDGA2 | c.1585A>G p.T529A (on ENST00000399232 / NM_001113498.2; = p.T231A on NM_182830.4) | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as COSV62092331; called by muse, mutect2, varscan2
- MED12 | c.4102A>C p.K1368Q | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV61339636; called by muse, mutect2, varscan2
- MINDY3 | c.445T>C p.F149L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53220355; called by muse, mutect2
- MROH9 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs746884765, COSV63011309, COSV63012840; called by muse, mutect2, varscan2
- MTUS2 | c.2423G>T p.S808I | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV70916736; called by muse, mutect2, varscan2
- MUC6 | c.4040C>T p.T1347I | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV70141320; called by muse, mutect2, varscan2
- MYBPH | c.473T>C p.M158T | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758333463, COSV55138107; called by muse, mutect2, varscan2
- MYRIP | c.435C>A p.H145Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV56868765; called by muse, mutect2, varscan2
- NAA40 | c.56G>C p.R19P | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.969); catalogued as COSV58160932; called by muse, mutect2
- NAALAD2 | c.797-1G>A p.X266_splice | Splice Site (SNP) | VAF 31/140 reads (22%) | catalogued as COSV58960949; called by muse, mutect2, varscan2
- NAV3 | c.642G>T p.Q214H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1480926373, COSV57078980; called by muse, mutect2, varscan2
- NCOA3 | c.4140G>T p.Q1380H (on ENST00000371998 / NM_181659.3; = p.Q1376H on NM_006534.4) | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.984); catalogued as COSV59068501, COSV59072607; called by muse, mutect2
- NEB | c.8444C>G p.P2815R | Missense Mutation (SNP) | VAF 58/323 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV51382724; called by muse, mutect2, varscan2
- NLRC5 | c.1777G>T p.A593S | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as COSV52654850; called by muse, mutect2, varscan2
- NOTCH4 | c.636T>A p.H212Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.377); catalogued as COSV66680611; called by muse, mutect2, varscan2
- NPFFR2 | c.1128G>C p.K376N | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as COSV58149586; called by muse, mutect2, varscan2
- NRBP1 | c.892C>G p.P298A | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV51994174; called by muse, mutect2, varscan2
- NRK | c.3292G>T p.D1098Y | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV54589889, COSV54596336; called by muse, mutect2, varscan2
- NRP2 | c.648G>T p.W216C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55928136; called by muse, mutect2, varscan2
- NTM | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV66179640; called by muse, mutect2, varscan2
- NUP37 | c.650G>T p.C217F | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV51837734; called by muse, mutect2, varscan2
- OBSCN | c.17859G>A p.L5953= | Splice Region (SNP) | VAF 4/23 reads (17%) | catalogued as COSV52773078; called by muse, mutect2
- ODF3B | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52687749; called by muse, mutect2
- OGA | c.429C>G p.I143M | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.934); catalogued as COSV63381632; called by muse, mutect2, varscan2
- OR10G3 | c.152C>A p.A51E | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as COSV57810226; called by muse, mutect2, varscan2
- OR2AK2 | c.697G>T p.G233* | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as COSV63552670; called by muse, mutect2, varscan2
- OR4C13 | c.388T>A p.Y130N | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV73648672, COSV73648746; called by muse, mutect2, varscan2
- OR51I1 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 42/131 reads (32%) | catalogued as COSV66507597, COSV66507877; called by muse, mutect2, varscan2
- OR5B2 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.046); catalogued as COSV56908205, COSV56909211; called by muse, mutect2, varscan2
- OR6V1 | c.74T>A p.L25Q | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69237224; called by muse, mutect2, varscan2
- OR7D4 | c.805C>A p.Q269K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV58071685; called by muse, mutect2, varscan2
- OR8J3 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100040613; called by muse, varscan2
- OR9G1 | c.727C>A p.H243N | Missense Mutation (SNP) | VAF 49/376 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1048188702, COSV56450460; called by muse, varscan2
- P2RY14 | c.943A>G p.K315E | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV56378494; called by muse, mutect2, varscan2
- P2RY8 | c.151C>A p.R51S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as COSV67177039, COSV67177283; called by muse, mutect2, varscan2
- PAPPA2 | c.1457C>A p.P486Q | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV62777982, COSV62780998; called by muse, mutect2, varscan2
- PCDH11X | c.2229C>G p.D743E | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53464460; called by muse, mutect2, varscan2
- PCDHA7 | c.2051T>C p.L684S | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV65336961; called by muse, mutect2, varscan2
- PCDHA9 | c.96C>A p.H32Q | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); catalogued as COSV65326422; called by muse, mutect2, varscan2
- PCDHB12 | c.1636C>A p.L546M | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); catalogued as COSV53396459; called by muse, mutect2, varscan2
- PDE3A | c.2566-2A>T p.X856_splice | Splice Site (SNP) | VAF 19/108 reads (18%) | catalogued as COSV62972656; called by muse, mutect2, varscan2
- PHKA1 | c.3397G>C p.V1133L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV59805675; called by muse, mutect2, varscan2
- PIAS1 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV51031907; called by muse, mutect2
- PLXNB2 | c.3715G>T p.E1239* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV63781635; called by muse, mutect2, varscan2
- PNLDC1 | c.1305G>C p.E435D | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV51705451; called by muse, mutect2, varscan2
- POTED | c.336C>A p.S112R | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.273); catalogued as rs759586364, COSV55048139; called by muse, mutect2, varscan2
- PPFIA2 | c.1794C>A p.H598Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs375047499, COSV61031825; called by muse, mutect2, varscan2
- PPP2R1A | c.643G>C p.D215H | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59044285; called by muse, mutect2, varscan2
- PRAMEF1 | c.275A>G p.K92R | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.597); catalogued as COSV100179613; called by muse, mutect2, varscan2
- PRR16 | c.344C>T p.T115M (on ENST00000407149 / NM_001300783.2; = p.T92M on NM_016644.2) | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773682575, COSV65399441; called by muse, mutect2, varscan2
- PRRC2C | c.2021C>G p.P674R (on ENST00000367742; = p.P672R on NM_015172.4) | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58905189; called by muse, mutect2, varscan2
- PRX | c.2567C>T p.S856L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52529876; called by muse, mutect2, varscan2
- PSG3 | c.1118A>T p.Q373L | Missense Mutation (SNP) | VAF 79/363 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV59504151; called by muse, mutect2, varscan2
- PYHIN1 | c.1423G>T p.V475L | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV63730871; called by muse, mutect2, varscan2
- RADX | c.917G>T p.S306I | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV65318558; called by muse, mutect2, varscan2
- RDX | c.215A>T p.K72I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58193716; called by muse, mutect2, varscan2
- RETREG3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/86 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as COSV52221133; called by muse, mutect2, varscan2
- RGMB | c.1152T>A p.F384L (on ENST00000513185 / NM_001366508.1; = p.F425L on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57565565; called by muse, mutect2, varscan2
- RPE65 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV52013547, COSV52015838, COSV52016741; called by muse, mutect2, varscan2
- RPLP0 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as rs747200774, COSV56107608; called by muse, mutect2, varscan2
- RTP4 | c.70A>T p.T24S | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV52018408; called by muse, mutect2, varscan2
- RUBCN | c.1920G>T p.M640I | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV56366056; called by muse, mutect2, varscan2
- RWDD1 | c.262G>C p.A88P | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV63972471; called by muse, mutect2
- SCARB1 | c.205T>A p.F69I | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV55547501; called by muse, mutect2, varscan2
- SCN11A | c.4813G>C p.E1605Q | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56569960; called by muse, mutect2, varscan2
- SCN11A | c.4034A>C p.Q1345P | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV56569965; called by muse, mutect2
- SEC14L4 | c.539C>A p.A180E | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs762499785, COSV55399658; called by muse, mutect2, varscan2
- SEPTIN14 | c.315G>C p.L105F | Missense Mutation (SNP) | VAF 766/1129 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66427703, COSV66429558, COSV66432027; called by muse, mutect2, varscan2
- SHROOM4 | c.3207C>A p.S1069R | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as rs1324837830, COSV56789117; called by muse, mutect2, varscan2
- SHROOM4 | c.2974A>G p.K992E | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); catalogued as COSV56789131; called by muse, mutect2, varscan2
- SLC1A4 | c.922C>A p.H308N | Missense Mutation (SNP) | VAF 24/415 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52234438; called by muse, mutect2
- SLC30A5 | c.2114G>C p.R705T | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as COSV67449492; called by muse, mutect2, varscan2
- SLC39A10 | c.1101G>T p.L367F | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62767365; called by muse, mutect2, varscan2
- SLC7A8 | c.1510A>G p.T504A | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV57553997; called by muse, mutect2, varscan2
- SLF2 | c.2059A>T p.K687* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV53273618; called by muse, mutect2, varscan2
- SMPD4 | c.1541A>T p.Q514L (on ENST00000409031 / NM_017951.4; = p.Q485L on NM_017751.4) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV60080176; called by muse, mutect2, varscan2
- SOCS2 | c.560T>A p.L187Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61392186; called by muse, mutect2, varscan2
- SP4 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as COSV56022669, COSV56023924; called by muse, mutect2, varscan2
- SPIN4 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV58738001; called by muse, mutect2, varscan2
- SPNS1 | c.968T>C p.L323P | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57954683; called by muse, mutect2, varscan2
- SPRED2 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100710147; called by muse, mutect2, varscan2
- SPTB | c.4292G>A p.R1431Q | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as rs943876155, COSV67631723; called by muse, mutect2, varscan2
- SRPX2 | c.1171C>A p.R391S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65933605, COSV65934805; called by muse, mutect2, varscan2
- STAB2 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV66338762; called by muse, mutect2, varscan2
- STAG2 | c.3594+1G>C p.X1198_splice | Splice Site (SNP) | VAF 47/199 reads (24%) | catalogued as rs777484689, COSV54358138, COSV54373163; called by muse, mutect2, varscan2
- STAT3 | c.1946C>G p.S649* | Nonsense Mutation (SNP) | VAF 39/296 reads (13%) | catalogued as COSV52886828, COSV52887317; called by muse, mutect2, varscan2
- SYMPK | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV55611540; called by muse, mutect2, varscan2
- SYT3 | c.1281G>A p.S427= | Splice Region (SNP) | VAF 7/21 reads (33%) | catalogued as rs778913847, COSV58896509; called by muse, mutect2, varscan2
- TAC1 | c.100T>A p.W34R | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV59987260, COSV59987408; called by muse, mutect2, varscan2
- TAF2 | c.2465T>A p.L822* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as COSV65418119; called by muse, mutect2, varscan2
- TBC1D8B | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs202142436, COSV52178184; called by muse, mutect2, varscan2
- TBX5 | c.805T>A p.S269T | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as CD004680, COSV59861101; called by muse, mutect2, varscan2
- TCEAL6 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV101035909, COSV65653934; called by muse, mutect2, varscan2
- TENM1 | c.6617G>T p.G2206V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV104427795, COSV64431629; called by muse, mutect2, varscan2
- TENM1 | c.6616G>A p.G2206R | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64431633; called by muse, mutect2, varscan2
- TFAP2D | c.876G>T p.L292F | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV50415269, COSV50429099; called by muse, mutect2, varscan2
- THOC2 | c.1771G>C p.D591H | Missense Mutation (SNP) | VAF 75/299 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55545685; called by muse, mutect2, varscan2
- THSD7A | c.4339C>A p.P1447T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV70264570; called by muse, mutect2, varscan2
- TLDC2 | c.406A>T p.T136S | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.531); catalogued as COSV54114288; called by muse, mutect2
- TMEM63A | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 37/283 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV64763040; called by muse, mutect2, varscan2
- TMPRSS15 | c.772C>A p.R258S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.114); catalogued as COSV53039591, COSV53044297; called by muse, mutect2, varscan2
- TNXB | c.11274G>C p.K3758N (on ENST00000647633; = p.K3511N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV64478763; called by muse, mutect2, varscan2
- TPR | c.5650C>G p.Q1884E | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1019830985, COSV66601318; called by muse, mutect2, varscan2
- TPTE | c.484G>T p.D162Y (on ENST00000618007 / NM_199261.4; = p.D144Y on NM_199259.4) | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs779972291; called by muse, mutect2, varscan2
- TRIM46 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV55278833, COSV99826017; called by muse, mutect2, varscan2
- TRPV6 | c.1536C>G p.F512L | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.746); catalogued as COSV63891724; called by muse, mutect2, varscan2
- TSHZ1 | c.1144G>C p.D382H (on ENST00000580243 / NM_001308210.2; = p.D337H on NM_005786.6) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as COSV100433513, COSV59009279; called by muse, mutect2, varscan2
- TSPYL6 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as rs1465893390, COSV57814614; called by muse, mutect2, varscan2
- TTC17 | c.827A>T p.H276L | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as COSV50008464; called by muse, mutect2, varscan2
- TTC17 | c.1611C>A p.S537R | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV50008475; called by muse, mutect2, varscan2
- TTLL3 | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.067); catalogued as COSV59614380; called by muse, mutect2, varscan2
- TTN | c.18393G>T p.M6131I (on ENST00000591111; = p.M5204I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | PolyPhen benign (0.131); catalogued as COSV59934374, COSV60050478; called by muse, mutect2, varscan2
- TWF1 | c.257T>C p.I86T | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1404504507, COSV57300576; called by muse, mutect2, varscan2
- TYW1 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 36/770 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62752524; called by muse, mutect2
- USP34 | c.9823G>C p.D3275H | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV63724991; called by muse, mutect2
- USP34 | c.4172C>G p.S1391C | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV68401178; called by muse, mutect2
- USP6NL | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV53211265, COSV99509495; called by muse, mutect2
- VBP1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV53972484; called by muse, mutect2, varscan2
- VRK3 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1372747297, COSV57465693; called by muse, mutect2, varscan2
- VWF | c.3590C>A p.P1197Q | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as rs372171661, COSV54619953; called by muse, mutect2, varscan2
- WDR5B | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV58072558; called by muse, mutect2, varscan2
- XYLT1 | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54484163; called by muse, mutect2, varscan2
- YTHDC2 | c.1423G>T p.D475Y | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV50740579; called by muse, mutect2, varscan2
- ZAN | c.7652C>A p.A2551E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as COSV61808915, COSV61814787; called by muse, mutect2, varscan2
- ZBTB33 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV58533913; called by muse, mutect2
- ZBTB38 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV58541592; called by muse, mutect2, varscan2
- ZDHHC15 | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as COSV64901732; called by muse, mutect2, varscan2
- ZDHHC17 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs754307156, COSV58351018; called by muse, mutect2, varscan2
- ZFAND6 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1164259359, COSV55711796; called by muse, mutect2
- ZFP36L2 | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56698042, COSV56698102; called by muse, mutect2, varscan2
- ZNF133 | c.782A>G p.Q261R (on ENST00000316358 / NM_001352454.2; = p.Q260R on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV60366980; called by muse, mutect2, varscan2
- ZNF219 | c.2018C>G p.A673G | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV53880292; called by muse, mutect2, varscan2
- ZNF229 | c.291C>G p.F97L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52161823; called by muse, mutect2, varscan2
- ZNF443 | c.1649A>G p.H550R | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1378346203, COSV56891652; called by muse, mutect2, varscan2
- ZNF454 | c.991A>C p.N331H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs776670804, COSV100195293, COSV60768324; called by muse, mutect2, varscan2
- ZNF540 | c.58T>C p.W20R | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57109229; called by muse, mutect2, varscan2
- ZNF565 | c.989G>C p.R330P (on ENST00000355114; = p.R290P on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.626); catalogued as COSV100411998, COSV58410877; called by muse, mutect2
- ZNF789 | c.704G>C p.G235A | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV58874353; called by muse, mutect2, varscan2
- ZNF829 | c.1073G>C p.R358T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV66986321; called by muse, mutect2, varscan2
- ZP4 | c.233G>C p.R78T | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs762309422, COSV63911938, COSV63913795; called by muse, mutect2, varscan2
- APBA2 | c.1797del p.N599Kfs*2 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- CPNE4 | c.99del p.G34Afs*33 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | called by mutect2, pindel, varscan2
- MEAK7 | c.372del p.E125Kfs*17 | Frame Shift Del (DEL) | VAF 27/164 reads (16%) | called by mutect2, pindel, varscan2
- MRC1 | c.3913+2T>C p.X1305_splice | Splice Site (SNP) | VAF 53/371 reads (14%) | called by muse, mutect2, varscan2
- MRC1 | c.4295G>C p.S1432T | Missense Mutation (SNP) | VAF 157/570 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PPFIA3 | c.3354+1_3354+16del p.X1118_splice | Splice Site (DEL) | VAF 14/94 reads (15%) | called by mutect2, pindel
- ACTA1 | c.429C>G p.S143= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV64203327, COSV64203677; called by muse, mutect2, varscan2
- ANKRD11 | c.813G>A p.L271= | Silent (SNP) | VAF 36/283 reads (13%) | catalogued as COSV56360703; called by muse, mutect2, varscan2
- ARHGAP9 | c.2157G>T p.R719= (on ENST00000393797 / NM_001319850.2; = p.R700= on NM_032496.4) | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV57361736; called by muse, mutect2, varscan2
- ATF4 | c.381C>G p.V127= | Silent (SNP) | VAF 60/292 reads (21%) | catalogued as COSV57478891, COSV57478921; called by muse, mutect2, varscan2
- BRDT | c.612G>T p.A204= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV62864935; called by muse, mutect2, varscan2
- C1QTNF5 | c.546C>T p.F182= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV60990603; called by muse, mutect2, varscan2
- CACNA1D | c.5910G>A p.Q1970= (on ENST00000350061 / NM_001128840.3; = p.Q1990= on NM_000720.4) | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV55446722; called by muse, mutect2, varscan2
- CAD | c.690C>T p.P230= | Silent (SNP) | VAF 63/156 reads (40%) | catalogued as COSV53026687; called by muse, mutect2, varscan2
- CALR | c.1038G>A p.T346= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs1306466845, COSV57124801; called by muse, mutect2, varscan2
- CAPRIN2 | c.2073A>G p.S691= | Silent (SNP) | VAF 34/142 reads (24%) | catalogued as COSV51832460; called by muse, mutect2, varscan2
- CYP2A13 | c.51G>A p.V17= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs71579360, COSV57837740; called by muse, mutect2, varscan2
- DLG3 | c.1671G>A p.Q557= (on ENST00000374360 / NM_021120.4; = p.Q220= on NM_020730.3) | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs982541905, COSV52082229; called by muse, mutect2, varscan2
- EPS8 | c.918T>C p.G306= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV55530660; called by muse, mutect2, varscan2
- FAM135B | c.2364C>G p.T788= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV52723950, COSV52749363; called by muse, mutect2, varscan2
- FLVCR2 | c.1041A>G p.G347= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV53161100; called by muse, mutect2, varscan2
- GC | c.159C>A p.P53= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV56737232; called by muse, mutect2
- GSDMB | c.321A>G p.S107= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV58780740; called by muse, mutect2, varscan2
- HCN3 | c.549G>T p.V183= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV64233998; called by muse, mutect2, varscan2
- KCNA6 | c.765G>T p.G255= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as COSV54975165; called by muse, mutect2, varscan2
- KCNH1 | c.1359G>T p.S453= (on ENST00000271751 / NM_172362.3; = p.S426= on NM_002238.4) | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as COSV55081074, COSV55104814; called by muse, mutect2, varscan2
- KCNK7 | c.768C>T p.F256= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs752411378, COSV58419557; called by muse, mutect2, varscan2
- KIF13B | c.2118G>A p.E706= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV73054409; called by muse, mutect2, varscan2
- KIFAP3 | c.1782C>T p.L594= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV63031369, COSV63033676; called by muse, mutect2, varscan2
- KRTAP10-5 | c.636C>T p.T212= | Silent (SNP) | VAF 51/159 reads (32%) | catalogued as rs1555924701, COSV59961683; called by muse, mutect2, varscan2
- MDC1 | c.6141T>G p.P2047= | Silent (SNP) | VAF 8/131 reads (6%) | catalogued as COSV64524552; called by muse, mutect2
- MUC16 | c.37968C>G p.L12656= | Silent (SNP) | VAF 32/348 reads (9%) | catalogued as COSV67465010; called by muse, mutect2
- MUC6 | c.4041C>A p.T1347= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as COSV70141314; called by muse, mutect2, varscan2
- MYCBP2 | c.6099C>G p.V2033= (on ENST00000357337; = p.V2071= on NM_015057.5) | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as COSV62018526; called by muse, mutect2, varscan2
- MYH13 | c.2250C>A p.L750= | Silent (SNP) | VAF 52/107 reads (49%) | catalogued as rs1204372036, COSV52820789; called by muse, mutect2, varscan2
- MYH4 | c.4230T>C p.A1410= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV55118016; called by muse, mutect2, varscan2
- NEIL3 | c.975G>T p.V325= | Silent (SNP) | VAF 59/169 reads (35%) | catalogued as COSV52810348; called by muse, mutect2, varscan2
- NLRP13 | c.333C>G p.T111= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV61621636; called by muse, mutect2, varscan2
- NRK | c.555G>T p.L185= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as COSV54596318; called by muse, varscan2
- NRROS | c.69C>T p.S23= | Silent (SNP) | VAF 10/137 reads (7%) | catalogued as rs776433247, COSV60745867; called by muse, mutect2
- OR2T1 | c.387G>T p.L129= | Silent (SNP) | VAF 37/162 reads (23%) | catalogued as COSV63541772, COSV63541877; called by muse, mutect2, varscan2
- OR2T3 | c.393T>C p.V131= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs751655264, COSV100613180; called by muse, mutect2, varscan2
- OR7D4 | c.804C>A p.S268= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV58071691; called by muse, mutect2, varscan2
- OR9G1 | c.375C>A p.I125= | Silent (SNP) | VAF 15/216 reads (7%) | catalogued as rs1427986821, COSV56450447, COSV56454312; called by muse, mutect2
- P2RY10 | c.918C>T p.Y306= | Silent (SNP) | VAF 68/291 reads (23%) | catalogued as rs757811875, COSV50681266; called by muse, mutect2, varscan2
- PAPPA2 | c.1458A>C p.P486= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV62777990; called by muse, mutect2, varscan2
- PAX8 | c.1047C>G p.A349= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV54508452; called by muse, mutect2
- PCDHB13 | c.1509G>T p.L503= | Silent (SNP) | VAF 67/178 reads (38%) | catalogued as COSV53396464; called by muse, mutect2, varscan2
- PGRMC1 | c.156G>T p.A52= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV54292662; called by muse, mutect2, varscan2
- PJA1 | c.45A>T p.G15= | Silent (SNP) | VAF 39/161 reads (24%) | catalogued as COSV64053139; called by muse, mutect2, varscan2
- PNLIPRP3 | c.169C>T p.L57= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as COSV65047957; called by muse, mutect2, varscan2
- POPDC3 | c.357G>A p.L119= | Silent (SNP) | VAF 22/175 reads (13%) | catalogued as COSV54644086; called by muse, mutect2, varscan2
- PXMP2 | c.366C>T p.L122= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as COSV58095239; called by muse, mutect2, varscan2
- RNF43 | c.1440C>T p.V480= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV68458007; called by muse, mutect2, varscan2
- SALL3 | c.3015C>T p.F1005= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV73306043; called by muse, mutect2, varscan2
- SCN3B | c.129G>C p.L43= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV54799262; called by muse, mutect2, varscan2
- SEPHS2 | c.996A>G p.Q332= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV72100755; called by muse, mutect2, varscan2
- SPATA46 | c.762C>A p.G254= | Silent (SNP) | VAF 77/376 reads (20%) | catalogued as rs201331788, COSV62632712, COSV62634810; called by muse, mutect2, varscan2
- STAP2 | c.414C>T p.V138= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV74070985; called by mutect2, varscan2
- TANGO6 | c.1618A>C p.R540= | Silent (SNP) | VAF 41/277 reads (15%) | catalogued as COSV55765206; called by muse, mutect2, varscan2
- TBC1D8B | c.120G>A p.G40= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV52178724, COSV52180442; called by muse, mutect2, varscan2
- TBCC | c.366G>T p.A122= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV55130650; called by muse, mutect2
- TGIF2 | c.507G>A p.R169= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV65836451; called by muse, mutect2, varscan2
- TMA7 | c.9C>T p.G3= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs1058384; called by muse, mutect2, varscan2
- TRIM49 | c.1014G>T p.S338= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100315971; called by muse, mutect2, varscan2
- ZNF804B | c.3867A>T p.T1289= | Silent (SNP) | VAF 43/237 reads (18%) | catalogued as COSV60827357; called by muse, mutect2, varscan2
- TFE3 | c.*183del | 3'UTR (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
